Surgical pathology report (de-identified scan), TCGA case TCGA-A3-3323, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-A3-3323-01A (Primary Tumor).

[page 1 of 2]
Laboratory Patient Report
Print Date/Time: [REDACTED]

Surgical Pathology

Histopathological Examination

Path#: [REDACTED]
Collected: [REDACTED] Received: [REDACTED] Complete [REDACTED]

Pre-Op Diagnosis : Right Renal Mass

Order Physician : [REDACTED]

Specimens : Kidney, Right

Frozen Diagnosis :

Report

: GROSS EXAMINATION:

The specimen is received in a container labeled with the name of the patient and labeled as kidney, right. The specimen consists of a kidney and attached perinephric fat which measures en bloc 21 x 14 x 7 cm and weighs 911 g. The ureter and vascular margins of resection are submitted in block 1. Sectioning into the kidney shows an oval golden yellow mass in the midportion of the specimen. The mass measures 5 x 4.5 x 4.0 cm. The mass is focally adherent to the overlying capsule. A section of the mass, adjacent capsule and inked surgical margin are submitted in block 2. The mass grossly extends into a calyx in an area measuring 1.5 x 1.4 cm. Sections of the mass are submitted in blocks 3-8. The pelvis and calices are not grossly dilated. The cortex averages 0.7 cm. A random section of kidney is submitted in block 9. The attached fat is dissected and no lymph nodes or adrenal tissue are identified. [REDACTED]

DIAGNOSIS BASED ON GROSS AND MICROSCOPIC EXAMINATION:

SPECIMEN TYPE: Radical nephrectomy.

LATERALITY: Right.

TUMOR SITE: Middle.

FOCALITY: Unifocal.

TUMOR SIZE (LARGEST TUMOR IF MULTIPLE):

Greatest dimension: 5.0 cm.

Additional dimensions: 4.5 x 4.0 cm.

MACROSCOPIC EXTENT OF TUMOR: Tumor limited to kidney.

HISTOLOGIC TYPE: Clear cell (conventional) renal carcinoma.

HISTOLOGIC GRADE (FUHRMAN NUCLEAR GRADE): Grade I.

EXTENT OF INVASION

PRIMARY TUMOR (PT): pT1b: Tumor more than 4.0 cm but not more than 7.0 cm in greatest dimension, limited to the kidney.

THIS CONFIDENTIAL AND PRIVILEGED DOCUMENT/INFORMATION IS PROTECTED BY
FEDERAL AND STATE LAW. UNAUTHORIZED DISCLOSURE, DISSEMINATION
OR DUPLICATION IS PROHIBITED

[page 2 of 2]
REGIONAL LYMPH NODES (PN): pNX: Cannot be assessed
DISTANT METASTASIS (PM): pMX: Cannot be assessed
MARGINS: Margins uninvolved by invasive carcinoma.
ADRENAL GLAND: Not present.
VENOUS (LARGE VESSEL) INVASION (V): Absent.
LYMPHATIC (SMALL VESSEL) INVASION (L): Absent.
ADDITIONAL PATHOLOGIC FINDINGS: None identified.

Intradepartmental consultation obtained.
Pathologic stage summary: pT1bNXMXG1.

[T-71000 M-83103 189.0 P3-44070]

Electronically Signed by
[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file 92522527-15df-4dfd-bdb2-b77673510731 (TCGA-A3-3323.C006CB87-E6FA-4860-AC25-961C5BEE46EB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).